Somatic mutation profile of tumor specimen TCGA-EO-A1Y5-01A (aliquot TCGA-EO-A1Y5-01A-11D-A159-09) from TCGA case TCGA-EO-A1Y5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 63.7 years (23,251 days).
Specimen TCGA-EO-A1Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59bf5389-e0cd-4b21-9cc0-f63d87ae58eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A1Y5-10A (Blood Derived Normal), aliquot TCGA-EO-A1Y5-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2715fe8e-e744-4ed3-9b8b-0bb4f918e559

The open-access MAF lists 73 somatic variants for this specimen: 56 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 15, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 33/60 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.710T>A p.M237K | Missense Mutation (SNP) | VAF 19/22 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765848205, COSV52682586, COSV53017093, COSV53037559, COSV53037741; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10291G>A p.V3431M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs754740151, COSV71288847; called by muse, mutect2, varscan2
- ACAD10 | c.878A>T p.H293L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV58157843; called by muse, mutect2
- ACADSB | c.207A>C p.K69N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV62550789; called by muse, mutect2, varscan2
- AJAP1 | c.869T>A p.L290H | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65451055; called by muse, mutect2, varscan2
- ARHGAP44 | c.154G>C p.A52P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52394851; called by muse, mutect2, varscan2
- C14orf39 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV58779384, COSV58782324; called by muse, mutect2, varscan2
- CAPZA3 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56853266; called by muse, mutect2, varscan2
- CARMIL3 | c.2403G>C p.E801D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV57726677; called by muse, mutect2
- CCDC122 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55709549; called by muse, mutect2
- CD58 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV59841825; called by muse, mutect2, varscan2
- CERK | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV53451555; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CLMN | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV54182820; called by muse, mutect2, varscan2
- CLVS2 | c.513A>T p.Q171H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51561677, COSV51563476; called by muse, mutect2, varscan2
- CNN1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs769850879, COSV52956102; called by muse, mutect2, varscan2
- COL19A1 | c.419A>C p.K140T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59574640; called by muse, mutect2, varscan2
- CPAMD8 | c.2824G>A p.D942N (on ENST00000651564; = p.D895N on NM_015692.5) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.465); catalogued as COSV71596670; called by muse, mutect2, varscan2
- CPNE2 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs138717944, COSV51962624; called by muse, mutect2, varscan2
- CREB5 | c.1297C>T p.Q433* (on ENST00000357727 / NM_182898.4; = p.Q426* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as COSV63221529; called by muse, mutect2, varscan2
- CTSO | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV70809198; called by mutect2, varscan2
- DCDC1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs374157559; called by muse, mutect2, varscan2
- DHX57 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as COSV54885817; called by muse, mutect2, varscan2
- DNAAF1 | c.1259C>A p.T420N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as COSV57577452; called by muse, mutect2, varscan2
- ECEL1 | c.2301_2310del p.N767Kfs*73 | Frame Shift Del (DEL) | VAF 12/14 reads (86%) | catalogued as COSV58812544; called by mutect2, varscan2
- EFHC2 | c.2146G>T p.E716* | Nonsense Mutation (SNP) | VAF 17/213 reads (8%) | catalogued as COSV59093452; called by muse, mutect2
- ERBIN | c.2616_2623del p.S872Rfs*11 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as COSV52317466; called by mutect2, pindel, varscan2
- FLVCR2 | c.815T>G p.F272C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53162591; called by muse, mutect2, varscan2
- GBP7 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as COSV54009843; called by muse, mutect2, varscan2
- GIMAP8 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs529904898, COSV56231736; called by muse, mutect2, varscan2
- GLG1 | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52667749, COSV99215408; called by muse, mutect2, varscan2
- GLRB | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as COSV52417527; called by muse, mutect2, varscan2
- GOT2 | c.1063C>G p.R355G | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55330493, COSV55331821; called by muse, mutect2, varscan2
- HECTD1 | c.338A>G p.N113S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV67946566; called by muse, mutect2, varscan2
- LENG9 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100002784, COSV56618421; called by muse, mutect2
- MDGA2 | c.1613G>T p.G538V (on ENST00000399232 / NM_001113498.2; = p.G240V on NM_182830.4) | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62094909; called by muse, mutect2, varscan2
- MIS18BP1 | c.2938C>A p.Q980K | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV60371125; called by muse, mutect2
- NOA1 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV51737275; called by muse, mutect2, varscan2
- OCM | c.62-2A>G p.X21_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as rs193133847, COSV54194635; called by muse, mutect2, varscan2
- PAMR1 | c.2006C>T p.A669V (on ENST00000619888 / NM_001001991.3; = p.A686V on NM_015430.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs143102071; called by muse, varscan2
- PPP2CA | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV51538251; called by muse, mutect2, varscan2
- SCAF8 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs769954775, COSV65791994; called by muse, mutect2, varscan2
- SI | c.433A>T p.S145C | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV52280939; called by muse, mutect2, varscan2
- SLC20A1 | c.1383G>T p.M461I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as COSV55611491; called by muse, mutect2
- SLC36A4 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58396316; called by muse, mutect2, varscan2
- SLC5A8 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs767362595, COSV73310712; called by muse, mutect2, varscan2
- SPINK5 | c.3028T>A p.L1010I | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV56255246; called by muse, mutect2
- SRSF11 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1195811835, COSV63936929; called by muse, mutect2, varscan2
- SULT1E1 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 16/195 reads (8%) | catalogued as COSV56947281; called by muse, mutect2
- TRMO | c.427T>C p.S143P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64291955; called by muse, mutect2, varscan2
- UBE3B | c.1899C>A p.D633E | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55094256; called by muse, mutect2, varscan2
- ZNF558 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV56863366; called by muse, mutect2, varscan2
- HNRNPD | c.789_794del p.Y263_Q265delins* | Nonsense Mutation (DEL) | VAF 90/201 reads (45%) | called by mutect2, pindel, varscan2
- IGHV1-18 | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLC9B2 | c.1487del p.L496Cfs*80 (on ENST00000362026 / NM_001370201.1; = p.L496Cfs*50 on NM_178833.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- C10orf71 | c.420C>A p.V140= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV60508391, COSV60509161; called by muse, mutect2, varscan2
- CSMD1 | c.10014A>G p.E3338= (on ENST00000520002; = p.E3337= on NM_033225.6) | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV59330623; called by muse, mutect2, varscan2
- ELAVL4 | c.372G>A p.P124= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs528644967, COSV63916163; called by muse, mutect2, varscan2
- ELFN2 | c.573C>T p.C191= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs145251233; called by muse, mutect2, varscan2
- FAM3B | c.42G>A p.V14= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV63613215; called by muse, mutect2, varscan2
- FCRL5 | c.2832T>C p.H944= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV62515076; called by muse, mutect2, varscan2
- HRNR | c.573C>A p.G191= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV64258738; called by muse, mutect2, varscan2
- KRT4 | c.711C>T p.A237= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs546100543, COSV53407596; called by muse, mutect2, varscan2
- NRXN2 | c.1215C>T p.D405= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs367937220, COSV99636335; called by mutect2, varscan2
- SCN3A | c.5367C>T p.D1789= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV51811090; called by muse, mutect2, varscan2
- SERPINB2 | c.282T>A p.I94= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV55092750; called by muse, mutect2, varscan2
- SNTG1 | c.1428T>G p.L476= | Silent (SNP) | VAF 16/250 reads (6%) | catalogued as COSV52446731; called by muse, mutect2
- TMEM132E | c.1629G>T p.R543= (on ENST00000321639; = p.R633= on NM_001304438.2) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58697400; called by muse, mutect2, varscan2
- VDAC3 | c.174A>G p.L58= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV50081560; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2416C>T p.L806= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV54296442; called by muse, mutect2
- IL4I1 | chr19:49901653 T>C | 5'Flank (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62010021, COSV62010272; called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1232C>A | RNA (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
